Somatic mutation profile of tumor specimen MP2PRT-PAUJRN-TBP1-B (aliquot MP2PRT-PAUJRN-TBP1-B-1-0-D-A835-36) from MP2PRT case MP2PRT-PAUJRN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (764 days).
Specimen MP2PRT-PAUJRN-TBP1-B: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 165c1e7b-c3d7-41e8-ac01-51dadfb7f241.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJRN-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJRN-NM1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f4fb498-2097-4062-8241-f4f7b0392543

The open-access MAF lists 12 somatic variants for this specimen: 12 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASP5 | c.533dup p.N178Kfs*3 | Frame Shift Ins (INS) | VAF 40/130 reads (31%) | catalogued as rs765105588; called by mutect2, varscan2
- GPR156 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 90/361 reads (25%) | catalogued as rs553212940, COSV59940911; called by muse, mutect2, varscan2
- GRID1 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs536754961, COSV60030856; called by muse, mutect2, varscan2
- ITGB8 | c.773A>G p.D258G | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1346554251; called by muse, mutect2, varscan2
- MYOM3 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 79/366 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs767696769, COSV58389451; called by muse, mutect2, varscan2
- ELOA2 | c.1695T>A p.D565E | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HDAC1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV4-69 | c.349A>C p.T117P | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, varscan2
- IGLV4-69 | c.355_359delinsCACC p.I119Hfs*? | Frame Shift Del (DEL) | VAF 30/129 reads (23%) | called by pindel, varscan2*
- LIMCH1 | c.658G>C p.V220L | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); called by muse, mutect2
- MYT1L | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 114/431 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC6A19 | c.1680C>A p.Y560* | Nonsense Mutation (SNP) | VAF 38/245 reads (16%) | called by muse, mutect2, varscan2
